Somatic mutation profile of tumor specimen TARGET-10-PAPAGK-03A (aliquot TARGET-10-PAPAGK-03A-01D) from TARGET case TARGET-10-PAPAGK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (853 days).
Specimen TARGET-10-PAPAGK-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bb2ee4b-40bd-4aca-82f6-834e3ebec8a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPAGK-10A (Blood Derived Normal), aliquot TARGET-10-PAPAGK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454792c0-255c-47c9-a99d-d20682e3caed

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Frame Shift Ins 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2504A>T p.D835V | Missense Mutation (SNP) | VAF 51/243 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909646, COSV54042199, COSV54043241, COSV54057031; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 33/440 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ANKRD30B | c.3594C>A p.N1198K | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100271691; called by mutect2, varscan2
- ATF7 | c.725_726insGGGAC p.I242Mfs*30 (on ENST00000548446 / NM_001366555.2; = p.I231Mfs*30 on NM_006856.3 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 15/101 reads (15%) | catalogued as COSV60645673; called by mutect2, pindel, varscan2
- FAM32A | c.271-1G>T p.X91_splice | Splice Site (SNP) | VAF 16/129 reads (12%) | catalogued as COSV54624771, COSV99655355; called by muse, mutect2, varscan2
- PPP1R16B | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55381039; called by muse, mutect2, varscan2
- SERPINB7 | c.253dup p.S85Ffs*2 | Frame Shift Ins (INS) | VAF 163/660 reads (25%) | catalogued as rs1434994276; called by mutect2, pindel, varscan2
- CREBBP | c.5513G>A p.C1838Y | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FCGBP | c.2033C>G p.T678S | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PTK7 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- MUC16 | c.22509A>G p.K7503= | Silent (SNP) | VAF 116/462 reads (25%) | catalogued as COSV67480790; called by muse, mutect2, varscan2
- PPP2CA | c.513G>A p.S171= | Silent (SNP) | VAF 76/391 reads (19%) | catalogued as rs778165477, COSV51538643; called by muse, mutect2, varscan2
